CCDI case PBBSYL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b8995349-80eb-4472-b793-f36a17950a22

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Desmoplastic nodular medulloblastoma: ICD-O-3 morphology code: 9471/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.8 years (1,404 days).

Biospecimens (3 samples)
- Sample 0DGL6K: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGL6M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DGL6P: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
